Somatic mutation profile of tumor specimen TCGA-SX-A7SP-01A (aliquot TCGA-SX-A7SP-01A-11D-A34Z-10) from TCGA case TCGA-SX-A7SP, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-SX-A7SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03e1cf74-42be-482b-bfbb-2e20f85022f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SP-10A (Blood Derived Normal), aliquot TCGA-SX-A7SP-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39b8689a-b36d-4660-b431-d2a1b27cb147

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Frame Shift Del 7, Splice Site 3, In Frame Ins 2, Nonsense Mutation 2, In Frame Del 1, Nonstop Mutation 1, RNA 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WNT7A | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs387907231, HM080062, COSV99541780; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.10968T>G p.F3656L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV101316558; called by muse, mutect2, varscan2
- ARIH2 | c.539-1G>T p.X180_splice | Splice Site (SNP) | VAF 40/82 reads (49%) | catalogued as COSV100711416; called by muse, mutect2, varscan2
- ASCC2 | c.1934C>G p.P645R | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100316519; called by muse, mutect2, varscan2
- BUB1B | c.2678+2T>C p.X893_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99807023; called by muse, mutect2, varscan2
- CDK5RAP2 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100575753; called by muse, mutect2, varscan2
- CORO2B | c.383A>T p.E128V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99963764; called by muse, mutect2, varscan2
- CPNE6 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs766705812, COSV99393800; called by muse, mutect2, varscan2
- CTBS | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV99759978; called by muse, mutect2, varscan2
- DDX10 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.734); catalogued as rs771566231, COSV100489985; called by muse, mutect2, varscan2
- DMD | c.3141G>C p.M1047I | Missense Mutation (SNP) | VAF 30/538 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV100822957; called by muse, mutect2
- DNTTIP2 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749832725, COSV100785220; called by muse, mutect2, varscan2
- DYTN | c.1383C>G p.H461Q | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101510907; called by muse, mutect2, varscan2
- GRM6 | c.675T>A p.Y225* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99179968; called by muse, mutect2, varscan2
- HNF4A | c.361T>C p.F121L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as COSV100291741; called by muse, mutect2, varscan2
- ISOC2 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99321358; called by muse, varscan2
- KCNG2 | c.1060_1061insTCA p.S354delinsFT | In Frame Ins (INS) | VAF 16/70 reads (23%) | catalogued as COSV100302124; called by muse*, mutect2, varscan2*
- KDM6A | c.3634C>T p.Q1212* | Nonsense Mutation (SNP) | VAF 250/521 reads (48%) | catalogued as COSV65037414; called by muse, mutect2, varscan2
- KIAA1109 | c.4085T>G p.F1362C | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs1343356159, COSV99177090; called by muse, mutect2, varscan2
- KIAA1109 | c.5617C>A p.Q1873K | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99177121; called by muse, mutect2, varscan2
- KIF2B | c.1793T>C p.V598A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs974799950, COSV52134437; called by muse, mutect2
- KLB | c.2779G>C p.G927R | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99962483; called by muse, mutect2, varscan2
- KNOP1 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV99575377; called by muse, mutect2, varscan2
- MDM1 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100292076; called by muse, mutect2, varscan2
- MIS18BP1 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 109/328 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as COSV100173283, COSV60369931; called by muse, mutect2, varscan2
- MRTFB | c.1621T>C p.S541P | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as COSV100371844; called by muse, mutect2, varscan2
- MUC17 | c.8602A>T p.S2868C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100075137; called by muse, mutect2, varscan2
- NFX1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.386); catalogued as rs1282455789, COSV100582476; called by muse, mutect2, varscan2
- OR10A6 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs374770684; called by muse, mutect2
- P2RX4 | c.357T>A p.I119= | Splice Region (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100078787; called by muse, mutect2, varscan2
- PCID2 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs773939084, COSV99872697; called by muse, mutect2, varscan2
- PCK1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100100990; called by muse, mutect2, varscan2
- PDCL3 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99959722; called by muse, mutect2, varscan2
- PDE3A | c.1518G>C p.K506N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100762828, COSV100762829; called by muse, mutect2, varscan2
- PITPNM2 | c.3727T>G p.F1243V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.719); catalogued as COSV99759681; called by muse, mutect2, varscan2
- PRKCSH | c.1470G>T p.M490I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52950932, COSV99371963; called by muse, mutect2, varscan2
- PRRC2B | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as rs1199044980, COSV61933531; called by muse, mutect2, varscan2
- PTBP2 | c.1584C>G p.N528K (on ENST00000426398 / NM_001300986.2; = p.N519K on NM_021190.4) | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV100930291; called by muse, mutect2, varscan2
- PTPRU | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100113785; called by mutect2, varscan2
- RBM44 | c.838T>C p.S280P (on ENST00000611254; = p.S914P on NM_001080504.2) | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV100390183; called by muse, mutect2, varscan2
- RLIM | c.1783C>A p.H595N | Missense Mutation (SNP) | VAF 159/348 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100223329; called by muse, mutect2, varscan2
- RNF34 | c.650C>A p.T217N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV100772162; called by muse, mutect2, varscan2
- SLC10A4 | c.759C>A p.F253L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99906812; called by muse, mutect2, varscan2
- SLC1A6 | c.1566G>T p.L522F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV99694229; called by muse, mutect2, varscan2
- SMARCA1 | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 205/412 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV100946735; called by muse, mutect2, varscan2
- SMCR8 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs577884923, COSV100329011; called by muse, mutect2, varscan2
- SNX29 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV100030212; called by muse, mutect2, varscan2
- TMEM106C | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs146483924; called by muse, mutect2, varscan2
- TMX2 | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560422; called by muse, mutect2, varscan2
- TNS1 | c.2218G>C p.G740R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV99411978; called by muse, mutect2, varscan2
- UBL7 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs967922427, COSV100795467; called by muse, mutect2, varscan2
- UBR4 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64391850, COSV64399060; called by muse, mutect2, varscan2
- WASHC5 | c.1088T>C p.L363P | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777485983, COSV100573104; called by muse, mutect2, varscan2
- ZNF862 | c.680T>A p.V227D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.216); catalogued as COSV99783844; called by muse, mutect2, varscan2
- ZSCAN1 | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.147); catalogued as COSV99992111; called by muse, mutect2, varscan2
- AK4 | c.468_470dup p.V157dup | In Frame Ins (INS) | VAF 38/139 reads (27%) | called by mutect2, pindel, varscan2
- CASC3 | c.457dup p.X153_splice | Splice Site (INS) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- CEP170 | c.3759_3761del p.K1253_H1254delinsN | In Frame Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- CNDP2 | c.1211_1226del p.V404Efs*3 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel*
- METTL6 | c.855_*8del | Nonstop Mutation (DEL) | VAF 25/104 reads (24%) | called by mutect2, pindel, varscan2
- MPI | c.278del p.N93Tfs*66 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- MYH15 | c.39_58del p.F13Lfs*18 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, pindel, varscan2
- PSMA6 | c.617_620del p.L206Qfs*9 | Frame Shift Del (DEL) | VAF 96/351 reads (27%) | called by mutect2, pindel, varscan2
- RPL37A | c.166_173del p.H56Ffs*62 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- STRAP | c.380del p.Y127Lfs*3 | Frame Shift Del (DEL) | VAF 50/173 reads (29%) | called by mutect2, pindel, varscan2
- ZNF326 | c.1564del p.E522Rfs*3 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- BMPER | c.1644G>A p.G548= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs781779445, COSV51828227; called by muse, mutect2, varscan2
- CNNM2 | c.222C>A p.I74= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100881764; called by muse, varscan2
- DSG1 | c.1434A>G p.T478= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV99936604; called by muse, mutect2, varscan2
- GAS8 | c.1332C>T p.A444= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs760609309, COSV99244217; called by muse, varscan2
- KCNRG | c.444A>T p.S148= | Silent (SNP) | VAF 57/161 reads (35%) | catalogued as COSV100078577; called by muse, mutect2, varscan2
- MATN1 | c.555G>A p.K185= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs1237255271, COSV101056446; called by muse, mutect2, varscan2
- MEX3B | c.1509T>A p.S503= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100314240; called by muse, mutect2, varscan2
- OR10A6 | c.795C>G p.G265= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as COSV100564363; called by muse, mutect2
- PDF | c.423G>A p.A141= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99846554; called by muse, mutect2
- PLD6 | c.180G>A p.A60= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100387620; called by muse, mutect2
- RNF111 | c.1375A>C p.R459= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100789218; called by muse, mutect2, varscan2
- SIPA1L1 | c.1395G>A p.V465= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100666093; called by muse, mutect2, varscan2
- TMF1 | c.1551C>T p.A517= | Silent (SNP) | VAF 28/573 reads (5%) | catalogued as COSV101275471; called by muse, mutect2
- YTHDC1 | c.1077C>T p.L359= (on ENST00000344157 / NM_001031732.4; = p.L341= on NM_133370.4) | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs768201756, COSV100704872; called by muse, mutect2, varscan2
- ZNF37A | c.624T>C p.N208= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV100697485; called by muse, mutect2, varscan2
- ZNF407 | c.6213G>A p.R2071= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100227231; called by muse, mutect2, varscan2
- ZNF616 | c.1599T>A p.R533= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV100348630; called by muse, mutect2, varscan2
- AC244258.1 | n.365G>A | RNA (SNP) | VAF 34/124 reads (27%) | catalogued as rs746340804; called by muse, mutect2, varscan2
- AP4S1 | c.306+4240G>A | Intron (SNP) | VAF 40/151 reads (26%) | catalogued as COSV53557817, COSV99364413; called by muse, varscan2
